Somatic mutation profile of tumor specimen MMRF_2683_1_BM_CD138pos (aliquot MMRF_2683_1_BM_CD138pos_T1_KHS5U_L14407) from MMRF case MMRF_2683, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 45.2 years (16,493 days).
Specimen MMRF_2683_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 312b112a-9538-414b-ae7d-96115f51edf5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2683_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2683_1_PB_WBC_C2_KHS5U_L14408; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b55d386-ca80-4be2-a04c-a8e02f300b13

The open-access MAF lists 128 somatic variants for this specimen: 55 protein-altering or splice-affecting, 15 silent, 58 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, 3'UTR 30, Intron 15, Silent 15, 3'Flank 4, 5'UTR 4, Frame Shift Ins 3, 5'Flank 3, RNA 2, Nonsense Mutation 2, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC092143.1 | c.1946C>T p.A649V | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.989); catalogued as rs878853258, CM107131; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DSG2 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs121913006, CM061700, COSV99852889; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 61/160 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ALB | c.1552G>A p.D518N | Missense Mutation (SNP) | VAF 81/219 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs75920790, CM910715; ClinVar: other / uncertain significance; called by muse, mutect2, varscan2
- ARHGAP44 | c.1353C>A p.F451L | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV52395316; called by muse, mutect2, varscan2
- B4GAT1 | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 79/332 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.836); catalogued as rs1455459346, COSV60820037; called by muse, mutect2, varscan2
- BCL11A | c.47A>C p.E16A | Missense Mutation (SNP) | VAF 40/73 reads (55%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.012); catalogued as COSV100184638; called by muse, mutect2, varscan2
- BCORL1 | c.1348G>A p.V450I | Missense Mutation (SNP) | VAF 83/167 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs1218505420; called by muse, mutect2, varscan2
- CLDN6 | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as rs1320376740; called by muse, mutect2, varscan2
- COCH | c.466C>T p.R156* (on ENST00000216361 / NM_001347720.1; = p.R91* on NM_004086.3) | Nonsense Mutation (SNP) | VAF 137/322 reads (43%) | catalogued as rs540895576, COSV53550459, COSV53551309; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL3A1 | c.2801C>T p.S934L | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as rs753621331, COSV58588341; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DCAF12L2 | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 9/222 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.34); catalogued as COSV100758530; called by muse, mutect2
- FBXO3 | c.872C>A p.S291* | Nonsense Mutation (SNP) | VAF 42/529 reads (8%) | catalogued as COSV55765851; called by muse, mutect2
- FBXO47 | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 96/183 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as rs1048041203; called by muse, mutect2, varscan2
- FES | c.1109C>T p.A370V | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.121); catalogued as rs760846247, COSV99060077; called by muse, mutect2, varscan2
- FRAS1 | c.10357G>A p.V3453I | Missense Mutation (SNP) | VAF 120/298 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.636); catalogued as rs376389651; called by muse, mutect2
- H1-4 | c.243G>C p.K81N | Missense Mutation (SNP) | VAF 65/152 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); catalogued as rs200686576, COSV56800958; called by muse, mutect2, varscan2
- IGHV2-70 | c.310A>C p.T104P | Missense Mutation (SNP) | VAF 54/120 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368647772; called by muse, varscan2
- IGHV2-70 | c.289A>C p.N97H | Missense Mutation (SNP) | VAF 80/160 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs368209907; called by muse, varscan2
- IGHV2-70 | c.230A>T p.D77V | Missense Mutation (SNP) | VAF 105/232 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.193); catalogued as rs546960655; called by muse, varscan2
- IGHV2-70 | c.94A>G p.K32E | Missense Mutation (SNP) | VAF 46/90 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs751761340; called by muse, varscan2
- IGHV4-34 | c.232A>G p.N78D | Missense Mutation (SNP) | VAF 98/192 reads (51%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs3814936; called by muse, varscan2
- IGLV3-1 | c.148T>A p.Y50N | Missense Mutation (SNP) | VAF 106/239 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as rs368495152; called by muse, mutect2, varscan2
- KALRN | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 75/266 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763633331, COSV53755131, COSV53780852; called by muse, mutect2, varscan2
- KIRREL1 | c.92C>T p.T31M | Missense Mutation (SNP) | VAF 176/287 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.561); catalogued as rs769466372; called by muse, mutect2, varscan2
- RIN1 | c.1136C>T p.A379V | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753952789; called by muse, mutect2, varscan2
- TDP1 | c.1567G>A p.G523R | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1312261210; called by muse, mutect2, varscan2
- TENT5C | c.415G>A p.V139M | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as rs766046722; called by muse, mutect2
- TLN2 | c.6437C>A p.A2146E | Missense Mutation (SNP) | VAF 145/302 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60889554; called by muse, mutect2, varscan2
- ACACA | c.4604G>A p.R1535Q | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2
- ANKRD44 | c.817T>C p.F273L | Missense Mutation (SNP) | VAF 9/217 reads (4%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.643); called by muse, mutect2
- ARHGAP28 | c.2113C>A p.P705T (on ENST00000383472 / NM_001366230.1; = p.P546T on NM_001010000.3) | Missense Mutation (SNP) | VAF 78/206 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CRB1 | c.128C>A p.S43Y | Missense Mutation (SNP) | VAF 61/196 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ERLIN1 | c.523C>T p.P175S | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); called by muse, mutect2
- HDLBP | c.1769_1772del p.K590Sfs*63 | Frame Shift Del (DEL) | VAF 60/328 reads (18%) | called by pindel, varscan2
- HLA-DQA2 | c.242A>G p.D81G | Missense Mutation (SNP) | VAF 93/307 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- INO80 | c.1975_1976dup p.S659Rfs*22 | Frame Shift Ins (INS) | VAF 31/223 reads (14%) | called by mutect2, pindel, varscan2
- LLGL1 | c.572G>T p.C191F | Missense Mutation (SNP) | VAF 53/109 reads (49%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- MYH1 | c.2108T>A p.L703Q | Missense Mutation (SNP) | VAF 16/273 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2
- NOL9 | c.2101dup p.M701Nfs*40 | Frame Shift Ins (INS) | VAF 67/432 reads (16%) | called by mutect2, pindel, varscan2
- PDZD8 | c.3430T>C p.S1144P | Missense Mutation (SNP) | VAF 117/234 reads (50%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PPP1CC | c.790G>T p.V264F | Missense Mutation (SNP) | VAF 24/681 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- PRKG2 | c.1634+2T>G p.X545_splice | Splice Site (SNP) | VAF 93/193 reads (48%) | called by muse, mutect2, varscan2
- PRPF40A | c.2237C>T p.S746L | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- PSMD14 | c.886A>G p.I296V | Missense Mutation (SNP) | VAF 11/272 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.012); called by muse, mutect2
- RYR2 | c.4856T>A p.V1619E | Missense Mutation (SNP) | VAF 66/135 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); called by muse, mutect2, varscan2
- SACS | c.3257C>T p.S1086F | Missense Mutation (SNP) | VAF 14/400 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); called by muse, mutect2
- SGCE | c.316dup p.E106Gfs*12 (on ENST00000647096; = p.E70Gfs*12 on NM_003919.3) | Frame Shift Ins (INS) | VAF 34/197 reads (17%) | called by mutect2, pindel, varscan2
- STT3B | c.2080G>C p.D694H | Missense Mutation (SNP) | VAF 56/161 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- SYDE1 | c.253C>A p.L85M | Missense Mutation (SNP) | VAF 56/196 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TEPSIN | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 31/183 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TERT | c.2216A>T p.Y739F | Missense Mutation (SNP) | VAF 1168/1847 reads (63%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTLL4 | c.1521G>C p.E507D | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- TYK2 | c.307T>G p.F103V | Missense Mutation (SNP) | VAF 78/294 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- VWA1 | c.599T>A p.I200N | Missense Mutation (SNP) | VAF 22/198 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- CD37 | c.30C>T p.L10= | Silent (SNP) | VAF 27/309 reads (9%) | called by muse, mutect2
- CRIP2 | c.576G>A p.A192= | Silent (SNP) | VAF 43/113 reads (38%) | catalogued as rs782072966; called by muse, mutect2, varscan2
- IGHV2-70 | c.252G>A p.L84= | Silent (SNP) | VAF 96/224 reads (43%) | catalogued as rs374732396; called by muse, varscan2
- IGHV3-33 | c.63G>T p.V21= | Silent (SNP) | VAF 38/79 reads (48%) | catalogued as rs767615399; called by muse, varscan2
- IGLL5 | c.141C>T p.S47= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as rs191888936, COSV73248969, COSV73251302; called by muse, mutect2, varscan2
- IGLV3-1 | c.78A>G p.P26= | Silent (SNP) | VAF 109/237 reads (46%) | catalogued as rs570281801; called by muse, mutect2, varscan2
- NRK | c.3765C>T p.V1255= | Silent (SNP) | VAF 106/242 reads (44%) | called by muse, mutect2, varscan2
- PDS5B | c.2805T>G p.L935= | Silent (SNP) | VAF 129/290 reads (44%) | called by muse, mutect2, varscan2
- PLSCR5 | c.744C>T p.V248= | Silent (SNP) | VAF 192/551 reads (35%) | catalogued as COSV101494465; called by muse, mutect2, varscan2
- RALA | c.165A>G p.V55= | Silent (SNP) | VAF 72/179 reads (40%) | catalogued as rs1255221380; called by muse, mutect2, varscan2
- ROBO3 | c.1563C>T p.C521= | Silent (SNP) | VAF 42/123 reads (34%) | catalogued as rs567531731, COSV67302302; called by muse, mutect2, varscan2
- RYR3 | c.8260C>T p.L2754= (on ENST00000389232; = p.L2755= on NM_001036.6) | Silent (SNP) | VAF 53/210 reads (25%) | called by muse, mutect2, varscan2
- SEMA4D | c.2517T>G p.L839= | Silent (SNP) | VAF 239/557 reads (43%) | called by muse, mutect2, varscan2
- SLC25A45 | c.426C>G p.P142= | Silent (SNP) | VAF 26/325 reads (8%) | called by muse, mutect2
- SLITRK6 | c.1147C>T p.L383= | Silent (SNP) | VAF 17/171 reads (10%) | catalogued as rs375484385, COSV68389869; called by muse, mutect2
- AGAP1 | c.1051-30144G>A | Intron (SNP) | VAF 5/24 reads (21%) | called by muse, mutect2
- ALX4 | c.*3388C>A | 3'UTR (SNP) | VAF 49/156 reads (31%) | called by muse, mutect2, varscan2
- ANO5 | c.*371T>G | 3'UTR (SNP) | VAF 23/82 reads (28%) | called by muse, mutect2, varscan2
- AP1B1 | c.1060-19T>C | Intron (SNP) | VAF 12/259 reads (5%) | called by muse, mutect2
- ARNTL2 | chr12:27421889 C>T | 3'Flank (SNP) | VAF 12/123 reads (10%) | called by muse, mutect2
- ASB13 | c.232-24A>T | Intron (SNP) | VAF 80/157 reads (51%) | called by muse, mutect2, varscan2
- BIRC3 | c.-154dup | 5'UTR (INS) | VAF 46/142 reads (32%) | called by mutect2, varscan2
- CELA3A | chr1:21998596 C>T | 5'Flank (SNP) | VAF 61/152 reads (40%) | called by muse, mutect2, varscan2
- CLMN | c.*39C>T | 3'UTR (SNP) | VAF 16/258 reads (6%) | called by muse, mutect2
- CNRIP1 | c.-532G>T | 5'UTR (SNP) | VAF 96/207 reads (46%) | called by muse, mutect2, varscan2
- CTDP1 | chr18:79679623 G>T | 5'Flank (SNP) | VAF 4/12 reads (33%) | called by muse, varscan2
- CYFIP2 | chr5:157395541 del GA | 3'Flank (DEL) | VAF 96/718 reads (13%) | called by mutect2, pindel, varscan2
- DBNL | c.*7744C>T | 3'UTR (SNP) | VAF 53/136 reads (39%) | called by muse, mutect2, varscan2
- DDX5 | c.442-40T>C | Intron (SNP) | VAF 87/186 reads (47%) | catalogued as rs782257440; called by muse, varscan2
- DIPK1B | c.199-119C>A | Intron (SNP) | VAF 69/237 reads (29%) | called by muse, mutect2, varscan2
- DMKN | c.1288-150G>A | Intron (SNP) | VAF 9/73 reads (12%) | called by muse, mutect2, varscan2
- EIF2AK3 | c.*443C>T | 3'UTR (SNP) | VAF 28/61 reads (46%) | called by muse, mutect2, varscan2
- FAM13A | c.1008-18069G>T | Intron (SNP) | VAF 108/255 reads (42%) | called by muse, mutect2, varscan2
- FIBCD1 | c.*1234C>T | 3'UTR (SNP) | VAF 70/341 reads (21%) | catalogued as rs944558420; called by muse, mutect2, varscan2
- GABRA3 | c.*271G>A | 3'UTR (SNP) | VAF 37/84 reads (44%) | called by muse, mutect2, varscan2
- GPRC5C | c.1187-182G>A | Intron (SNP) | VAF 18/165 reads (11%) | catalogued as rs1244977385; called by muse, mutect2, varscan2
- HGF | c.625+865A>C | Intron (SNP) | VAF 61/121 reads (50%) | called by muse, mutect2, varscan2
- HS2ST1 | c.*1690G>A | 3'UTR (SNP) | VAF 20/58 reads (34%) | called by muse, mutect2, varscan2
- HS6ST1P1 | n.754G>A | RNA (SNP) | VAF 8/28 reads (29%) | called by muse, mutect2, varscan2
- KIAA1109 | c.2794-66T>G | Intron (SNP) | VAF 44/113 reads (39%) | called by muse, mutect2, varscan2
- LMAN1 | c.*2565A>G | 3'UTR (SNP) | VAF 46/112 reads (41%) | called by muse, mutect2, varscan2
- LTB | c.208+71G>T | Intron (SNP) | VAF 73/135 reads (54%) | called by muse, mutect2, varscan2
- MEGF11 | c.2215+42T>C | Intron (SNP) | VAF 11/212 reads (5%) | called by muse, mutect2
- MIER1 | c.*1851T>C | 3'UTR (SNP) | VAF 59/118 reads (50%) | called by muse, mutect2, varscan2
- MIR663A | n.18C>T | RNA (SNP) | VAF 41/104 reads (39%) | called by muse, varscan2
- MPP7 | c.*580T>A | 3'UTR (SNP) | VAF 44/102 reads (43%) | called by muse, mutect2, varscan2
- MYO1E | c.-166A>T | 5'UTR (SNP) | VAF 132/248 reads (53%) | called by muse, mutect2, varscan2
- NIBAN1 | c.*415C>T | 3'UTR (SNP) | VAF 17/198 reads (9%) | called by muse, mutect2
- NLGN1 | c.*2022A>C | 3'UTR (SNP) | VAF 42/132 reads (32%) | called by muse, mutect2, varscan2
- PEA15 | c.*1550C>T | 3'UTR (SNP) | VAF 215/383 reads (56%) | called by muse, mutect2, varscan2
- PEAK1 | c.*4914G>A | 3'UTR (SNP) | VAF 14/181 reads (8%) | called by muse, mutect2
- PES1 | chr22:30592210 G>A | 5'Flank (SNP) | VAF 89/217 reads (41%) | called by muse, mutect2, varscan2
- PIK3CD | c.-138+2225T>A | Intron (SNP) | VAF 12/26 reads (46%) | called by muse, varscan2
- QPRT | c.*33G>A | 3'UTR (SNP) | VAF 197/423 reads (47%) | called by muse, mutect2, varscan2
- RASGEF1C | c.*697C>T | 3'UTR (SNP) | VAF 7/137 reads (5%) | catalogued as rs964980945; called by muse, mutect2
- RASSF2 | c.*1889A>C | 3'UTR (SNP) | VAF 66/146 reads (45%) | called by muse, mutect2
- RNF144B | c.-111C>T | 5'UTR (SNP) | VAF 49/107 reads (46%) | called by muse, mutect2, varscan2
- RNF7 | c.*2170G>A | 3'UTR (SNP) | VAF 67/205 reads (33%) | catalogued as rs1030330804; called by muse, mutect2, varscan2
- RRAS2 | c.108+16736A>G | Intron (SNP) | VAF 234/355 reads (66%) | catalogued as rs1327070365; called by muse, mutect2, varscan2
- RTF1 | c.*736A>T | 3'UTR (SNP) | VAF 75/275 reads (27%) | called by muse, mutect2, varscan2
- RXFP3 | c.*124G>A | 3'UTR (SNP) | VAF 36/134 reads (27%) | called by muse, varscan2
- SLAIN1 | c.560+639T>A | Intron (SNP) | VAF 12/30 reads (40%) | called by muse, mutect2
- SUSD5 | c.*1211C>T | 3'UTR (SNP) | VAF 5/75 reads (7%) | called by muse, mutect2
- SYBU | c.*509G>T | 3'UTR (SNP) | VAF 96/172 reads (56%) | called by muse, mutect2, varscan2
- SYNPO | c.*654C>T | 3'UTR (SNP) | VAF 170/679 reads (25%) | catalogued as rs903878262; called by muse, mutect2, varscan2
- SYT4 | c.*2069A>G | 3'UTR (SNP) | VAF 38/65 reads (58%) | called by muse, varscan2
- TBC1D8B | c.*647G>A | 3'UTR (SNP) | VAF 5/85 reads (6%) | called by muse, mutect2
- TOR3A | chr1:179097851 T>C | 3'Flank (SNP) | VAF 120/209 reads (57%) | called by muse, mutect2, varscan2
- TRAF3IP2 | chr6:111557377 A>G | 3'Flank (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2, varscan2
- TXNDC16 | c.*1632A>G | 3'UTR (SNP) | VAF 46/117 reads (39%) | called by muse, mutect2, varscan2
- TXNDC5 | c.*221_*225del | 3'UTR (DEL) | VAF 33/88 reads (38%) | called by mutect2, pindel, varscan2
- TYRP1 | c.*1002C>T | 3'UTR (SNP) | VAF 41/107 reads (38%) | called by muse, mutect2, varscan2
- WWC3 | c.*1118T>G | 3'UTR (SNP) | VAF 77/159 reads (48%) | called by muse, mutect2, varscan2
